Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A10S, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A10S-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Collection Date :

100-0-3
carcinoma, hepatocellular, NOS
8/7/03
Site: liver c22.0
LW 7/5/11

CLINICAL INFORMATION

The patient is with a history of **hepatocellular carcinoma** undergoes resection of the left liver lobe.

GROSS DESCRIPTIONS

One appropriately labeled, formalin-filled, container is received. It holds a 362 gram, 13.5 x 10.5 x 5.0 cm. tan/gray liver lobe with an 8.0 x 7.5 x 5.0 intact tumor mass protruding from the surface. There is a roughly spherical defect in the base of the specimen where tumor was given to tissue procurement. The surgical margin has been inked black. The cut tumor surface demonstrates central regions of yellow/orange necrosis and hemorrhage. The tumor appears well circumscribed and its closest distance to the surgical margin is 1.2 cm. No other masses are identified in the hepatic parenchyma. Representative sections are submitted as per block summary.

BLOCK SUMMARY

- 1-5 - tumor
- 6 - uninvolved parenchyma
- 7-8 - surgical margin

LIGHT MICROSCOPY

Light microscopic examination is performed.

Sections show a well circumscribed and apparently encapsulated tumor nodule composed of enlarged hyperchromatic hepatocytes arranged predominantly in a trabecular pattern. There is both a micro-trabecular as well as a macro-trabecular pattern. Focal pseudo-acinar structures are also seen. There are focal areas of tumor necrosis and hemorrhage. Focal changes suspicious for lymphovascular space invasion are observed in the capsule (section #8). There was a single nodule of tumor without any apparent satellite lesions. The tumor appears to be well differentiated and does not involve in the surgical margins. The adjacent liver tissue has a normal hepatic architecture without significant fibrosis. Steatosis was also absent.

DIAGNOSIS

- LIVER MASS, LEFT LOBE, PARTIAL HEPATITIC RESECTION
- **HEPATOCELLULAR CARCINOMA, WELL DIFFERENTIATED, PREDOMINANTLY TRABECULAR PATTERN, 8.0 CM IN GREATEST DIMENSION**
- SURGICAL MARGINS CLEAR

Source: NCI Genomic Data Commons file baf2e093-55cf-4d52-b931-a2d7776633dc (TCGA-BC-A10S.A0F69833-CBDD-492D-9564-AE8FB2F9CE3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).